Gene-level copy-number profile of tumor specimen ALCH-AELP-TTP1-A from ALCHEMIST case ALCH-AELP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,428 days).
Specimen ALCH-AELP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a284ca1-0318-42e9-8896-c9adf6d692c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/d52147ea-21df-4b8a-83a7-13bc85d99440

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,950; copy number 2: 54,870; copy number 3: 1,056; copy number 4: 41.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
